Surgical pathology report (de-identified scan), TCGA case TCGA-AN-A03Y, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Cureline, specimen TCGA-AN-A03Y-01A (Primary Tumor).

TSS Patient ID:

Case #: DOB: Sex: Female Ethnicity (Race):

Cancer Sample

Diagnosis: Breast Cancer Histological description: Infiltrative ductal carcinoma

Date of Procurement: Anatomic Site: Left Breast Tumor location: Primary

Tissue Specification: Tumor Specimen Matrix: Tissue Specimen Format: Frozen

Container: cryomold Type of Procurement: Radical mastectomy Grade: 2

T Stage: 2 N Stage: 0 M Stage: 0 Treatment: none

Treatment Details: n/a

Normal Sample

Anatomic Site: Blood Sample Type: Normal Type of Procurement: blood draw

Matrix: Blood Specimen Format: frozen Container: tube

Date of Procurement:

ICS-0-3
carcinoma, infiltrating duct, nos 8500/3
Site: breast, nos CSO.7 lw
10/21/11

lw 10/21/11

Source: NCI Genomic Data Commons file d567a219-2f78-4e78-aaa7-9703e8abeafd (TCGA-AN-A03Y.76734A82-9137-4DA4-871E-D4EC1BC33831.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).